MMRF case MMRF_2336 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dc664f0d-1881-4961-a95f-b8458ade2d76

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.2 years (23,093 days); ISS stage: I; Days to last known disease status: 780 days (2.1 years); Days to last follow up: 780 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 132 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 122 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 164 days; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 670 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 729 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 2.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 29.8 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.74 g/L; Beta 2 Microglobulin 3.48 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.95 ×10⁹/L; Absolute Neutrophil 4.79 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 1.89 mmol/L; Calcium 2.28 mmol/L; Albumin 38.9 g/L; Total Protein 8.53 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.91 mg/dL.
- Day 59 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 7.12 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 1.36 g/L; Beta 2 Microglobulin 2.48 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 7.22 ×10⁹/L; Absolute Neutrophil 4.33 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 54.8 µmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.31 g/dL; Glucose 4.84 mmol/L.
- Day 150 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 1.06 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.21 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.23 mmol/L; Albumin 42.4 g/L; Total Protein 6.74 g/dL; Glucose 6 mmol/L.
- Day 262 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 3.71 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 1.29 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.62 ×10⁹/L; Absolute Neutrophil 3.76 ×10⁹/L; Platelets 93.2 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 1.29 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 346 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.34 mg/dL; Immunoglobulin G 3.4 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.63 ×10⁹/L; Absolute Neutrophil 3.84 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.15 mmol/L; Albumin 43.4 g/L; Total Protein 6.24 g/dL; Glucose 4.9 mmol/L.
- Day 430 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 8.05 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 1.75 g/L; Beta 2 Microglobulin 2.39 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.99 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.25 mmol/L; Albumin 42.8 g/L; Total Protein 6.5 g/dL; Glucose 4.68 mmol/L.
- Day 542 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 9.97 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 1.08 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.28 mmol/L; Albumin 42.8 g/L; Total Protein 6.81 g/dL; Glucose 6.33 mmol/L.
- Day 598 (ECOG 1): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 1.23 g/L; Beta 2 Microglobulin 2.48 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.04 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.25 mmol/L; Albumin 42.8 g/L; Total Protein 6.71 g/dL; Glucose 4.57 mmol/L.
- Day 689 (ECOG 1): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.88 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.22 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 74.9 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 1.04 mmol/L; Calcium 2.08 mmol/L; Albumin 40.8 g/L; Total Protein 6.35 g/dL; Glucose 5.45 mmol/L.
- Day 780 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 3.68 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 2.12 ×10⁹/L; Absolute Neutrophil 1.09 ×10⁹/L; Platelets 48.5 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.33 mmol/L; Calcium 2.13 mmol/L; Albumin 38.4 g/L; Total Protein 5.44 g/dL; Glucose 9.19 mmol/L.

Other clinical attributes
- Day -18: Weight: 87 kg; Height: 154 cm.

Biospecimens (2 samples)
- Sample MMRF_2336_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_2336_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
